Somatic mutation profile of tumor specimen TCGA-RW-A681-01A (aliquot TCGA-RW-A681-01A-11D-A35D-08) from TCGA case TCGA-RW-A681, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 57.0 years (20,812 days).
Specimen TCGA-RW-A681-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 319a5394-1250-4075-bc50-4d28c8e917cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A681-10A (Blood Derived Normal), aliquot TCGA-RW-A681-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d9cdd954-31b3-46eb-b362-123cec495973

The open-access MAF lists 21 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 13, Silent 5, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1G3 | c.87A>T p.K29N | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1299331279; called by mutect2, varscan2
- DCDC1 | c.2582C>G p.S861C | Missense Mutation (SNP) | VAF 48/90 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.875); catalogued as COSV60834201; called by muse, mutect2, varscan2
- DIP2C | c.1164C>G p.F388L | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.378); catalogued as COSV55167795; called by muse, mutect2, varscan2
- TAS2R8 | c.320A>G p.Y107C | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as rs764442008; called by muse, mutect2, varscan2
- ZNF394 | c.1625G>A p.R542Q | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0.037); catalogued as rs764235626, COSV100529984, COSV61793399; called by muse, mutect2, varscan2
- ABCA13 | c.5132G>T p.G1711V | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- AMER1 | c.383C>T p.P128L | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- BICDL1 | c.1090-2A>G p.X364_splice | Splice Site (SNP) | VAF 31/96 reads (32%) | called by muse, mutect2, varscan2
- CLCA1 | c.134A>C p.E45A | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSDE1 | c.1487_1490del p.K496Rfs*14 (on ENST00000358528 / NM_001007553.3; = p.K465Rfs*14 on NM_007158.6) | Frame Shift Del (DEL) | VAF 31/38 reads (82%) | called by mutect2, pindel, varscan2
- FAM193B | c.1318G>A p.A440T | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- KIF2B | c.1498A>C p.T500P | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT35 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SVOPL | c.930G>T p.L310F (on ENST00000419765; = p.L158F on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TAOK2 | c.54_55del p.F19Lfs*4 | Frame Shift Del (DEL) | VAF 38/89 reads (43%) | called by pindel, varscan2
- WDR11 | c.363G>C p.W121C | Missense Mutation (SNP) | VAF 36/133 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CLEC4M | c.747A>G p.Q249= | Silent (SNP) | VAF 65/112 reads (58%) | catalogued as COSV50216765; called by muse, mutect2, varscan2
- PNPT1 | c.759A>G p.Q253= | Silent (SNP) | VAF 44/151 reads (29%) | catalogued as rs1021659426; called by muse, mutect2, varscan2
- SLIT1 | c.1356C>T p.D452= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs561139048; called by muse, mutect2, varscan2
- SPTBN2 | c.5940G>T p.A1980= | Silent (SNP) | VAF 57/58 reads (98%) | called by muse, mutect2, varscan2
- TTN | c.55563A>T p.V18521= (on ENST00000591111; = p.V11097= on NM_003319.4) | Silent (SNP) | VAF 61/181 reads (34%) | called by muse, mutect2, varscan2
